Somatic mutation profile of tumor specimen TCGA-EA-A43B-01A (aliquot TCGA-EA-A43B-01A-81D-A243-09) from TCGA case TCGA-EA-A43B, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 43.5 years (15,871 days).
Specimen TCGA-EA-A43B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14795c66-6749-46ae-b075-08c2b2c27fac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A43B-10A (Blood Derived Normal), aliquot TCGA-EA-A43B-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25114532-b5d5-4f98-adfe-abc3a7910ef3

The open-access MAF lists 178 somatic variants for this specimen: 126 protein-altering or splice-affecting, 48 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 48, Nonsense Mutation 5, 5'Flank 3, Frame Shift Del 2, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF5 | c.3998C>T p.S1333L | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99344950; called by muse, mutect2
- AFDN | c.5359G>A p.E1787K (on ENST00000447894 / NM_001366320.1; = p.E1706K on NM_001207008.1) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1276056876, COSV63537577; called by muse, mutect2
- AOPEP | c.2122C>T p.P708S (on ENST00000375315 / NM_001193329.1; = p.P609S on NM_032823.5) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.248); catalogued as COSV99948830; called by muse, mutect2, varscan2
- AP2B1 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99250889; called by muse, mutect2
- ATG4D | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs1311872290, COSV100521027, COSV58762733; called by muse, mutect2
- ATMIN | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100214518; called by muse, mutect2
- ATMIN | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV55146297; called by mutect2, varscan2
- BAP1 | c.1866G>C p.L622F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.077); catalogued as COSV99963443; called by muse, mutect2
- BSDC1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as rs1319084553, COSV61982127; called by muse, mutect2
- C1orf94 | c.1694C>T p.P565L (on ENST00000488417 / NM_001134734.2; = p.P375L on NM_032884.5) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs150314159; called by muse, mutect2, varscan2
- C3orf56 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV101228925, COSV67756148; called by muse, mutect2
- CACNA1E | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV62381909; called by muse, mutect2, varscan2
- CBWD2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.074); catalogued as COSV99380254; called by muse, mutect2
- CDH4 | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.305); catalogued as rs760981738, COSV64656530; called by muse, mutect2, varscan2
- CFHR5 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs776063846, COSV56821819, COSV56827323; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLEC16A | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101277805; called by muse, mutect2
- CMKLR1 | c.1077G>A p.M359I (on ENST00000312143 / NM_001142344.2; = p.M357I on NM_004072.3) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56441093; called by muse, mutect2
- CNTNAP2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV62251654; called by muse, mutect2, varscan2
- COL16A1 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54706869; called by mutect2, varscan2
- COL4A6 | c.3293G>A p.R1098K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV57867839; called by muse, mutect2, varscan2
- CYP4Z1 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); catalogued as COSV100497525; called by muse, mutect2
- DEPDC1B | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54007937, COSV54010402; called by mutect2, varscan2
- DHRS7B | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100683871; called by muse, mutect2
- DHX37 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV58135068; called by muse, mutect2, varscan2
- DPY19L3 | c.1460G>C p.W487S | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639114; called by muse, mutect2
- DVL1 | c.1345G>A p.D449N (on ENST00000378888 / NM_001330311.2; = p.D424N on NM_004421.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100229272; called by muse, mutect2
- DYNC1H1 | c.11737G>C p.E3913Q | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as COSV100794473; called by muse, mutect2
- EFCAB1 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.133); catalogued as COSV50618438; called by muse, mutect2
- ELL | c.1414G>C p.D472H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99442808; called by muse, mutect2, varscan2
- ELL | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53212932; called by muse, mutect2, varscan2
- ERBIN | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52317490; called by muse, mutect2, varscan2
- ESPL1 | c.6208G>C p.D2070H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54476072; called by muse, mutect2, varscan2
- FREM2 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV54839651; called by muse, mutect2
- FUBP1 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99627870; called by muse, mutect2
- GAB3 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV65819737, COSV65820613; called by muse, mutect2
- GPA33 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100900932; called by muse, mutect2
- GPR156 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100251137; called by muse, mutect2
- H2AX | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV53828488, COSV99597813; called by muse, mutect2
- HIF3A | c.802G>C p.D268H (on ENST00000377670 / NM_152795.4; = p.D199H on NM_022462.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52199133; called by mutect2, varscan2
- KCNA10 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100871398; called by muse, mutect2
- LAS1L | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs762931496, COSV56707530; called by muse, mutect2, varscan2
- LETMD1 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV50397793; called by muse, mutect2, varscan2
- LIG1 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99618530; called by muse, mutect2
- LIMK1 | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100283127, COSV60281885; called by muse, mutect2
- LTBP4 | c.2899G>C p.E967Q (on ENST00000308370 / NM_001042544.1; = p.E930Q on NM_003573.2) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52581309; called by muse, mutect2, varscan2
- MAP3K4 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100815059, COSV100815076; called by muse, mutect2
- MAP4K5 | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99184500; called by muse, mutect2
- MAP9 | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV60904110, COSV60904904; called by muse, mutect2, varscan2
- MDGA2 | c.2485C>G p.Q829E (on ENST00000399232 / NM_001113498.2; = p.Q531E on NM_182830.4) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100636308, COSV62095044; called by muse, mutect2, varscan2
- MFSD1 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV99963627; called by muse, mutect2
- MGMT | c.610G>C p.G204R (on ENST00000306010; = p.G173R on NM_002412.5) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV60027908; called by muse, mutect2, varscan2
- MIA2 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99697310; called by muse, mutect2
- MIB1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV55089401; called by muse, mutect2, varscan2
- MKI67 | c.4716G>C p.K1572N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV100896191; called by muse, mutect2
- MYO1H | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV60446189; called by muse, mutect2, varscan2
- MYO6 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs140235734, COSV64120895; called by muse, mutect2, varscan2
- MYO9B | c.3697G>C p.E1233Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV101261303, COSV68280872; called by muse, mutect2
- NCAPH2 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.237); catalogued as COSV55369312; called by muse, mutect2, varscan2
- NCKAP5 | c.5083G>A p.E1695K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100490130; called by muse, mutect2
- NEB | c.15844G>A p.D5282N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99415133; called by muse, mutect2
- NHS | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101196790, COSV66275687; called by muse, mutect2, varscan2
- NUFIP2 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837238; called by muse, mutect2
- OR1J2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.214); catalogued as COSV58944435; called by muse, mutect2, varscan2
- OR4N5 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV61320679; called by muse, mutect2
- OR5M10 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.15); catalogued as COSV73242338; called by muse, mutect2, varscan2
- PCDH1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1184593221, COSV54611980; called by muse, mutect2
- PCDHA3 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.532); catalogued as rs782279925, COSV100793243, COSV63542297; called by muse, mutect2, varscan2
- PCGF3 | c.672G>T p.W224C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62859549; called by muse, mutect2, varscan2
- PCNX1 | c.3154G>T p.V1052F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53095411; called by mutect2, varscan2
- PDZD7 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1404937734, COSV99827364; called by muse, mutect2
- PFAS | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1448699383, COSV100118764; called by muse, mutect2, varscan2
- PHYHIP | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV58688641; called by muse, mutect2, varscan2
- PIGB | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99380049; called by muse, mutect2
- PLEKHG7 | c.1730C>G p.S577* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100760039; called by muse, mutect2
- POLR2E | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.15); catalogued as COSV53123500; called by muse, mutect2
- POLR3G | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV67625449, COSV67625724; called by muse, mutect2, varscan2
- POPDC3 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54644283; called by muse, mutect2
- POPDC3 | c.562T>A p.S188T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54644297; called by muse, mutect2
- PRPF38A | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746322792, COSV57122538; called by mutect2, varscan2
- PSMG1 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV59000554; called by muse, mutect2, varscan2
- PTBP3 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57582047; called by muse, mutect2
- PTPRM | c.2771G>C p.R924T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs990397990, COSV59861602; called by mutect2, varscan2
- RIMS2 | c.1168C>G p.R390G (on ENST00000666250 / NM_001348490.2; = p.R198G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV99161757; called by muse, mutect2
- RIPK3 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99352957; called by muse, mutect2
- RNF145 | c.1742C>A p.S581Y (on ENST00000424310 / NM_001199383.2; = p.S609Y on NM_144726.2) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV99193256; called by muse, mutect2
- RNF146 | c.799G>C p.E267Q (on ENST00000368314 / NM_001242850.2; = p.E266Q on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as COSV58932690; called by muse, mutect2, varscan2
- RTL1 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs375169836; called by muse, mutect2, varscan2
- RUNDC3B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99712207; called by muse, mutect2
- SALL4 | c.2134C>T p.L712F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53850954; called by muse, mutect2, varscan2
- SDCCAG8 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100653890; called by muse, mutect2, varscan2
- SEC16A | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51529217; called by muse, mutect2
- SELENBP1 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100923598; called by muse, mutect2
- SH3TC1 | c.3642C>G p.F1214L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV55284602, COSV55287528; called by muse, mutect2, varscan2
- SLC25A21 | c.477G>C p.K159N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100490425; called by muse, mutect2
- SLC30A8 | c.573-1G>A p.X191_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV101438253; called by muse, mutect2
- SMG1 | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.634); catalogued as COSV101245238; called by muse, mutect2
- SNX27 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV64326502; called by muse, mutect2
- SPATA16 | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV63529693; called by muse, mutect2
- STAC2 | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61065617; called by muse, mutect2, varscan2
- STYXL1 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.158); catalogued as COSV50389222; called by muse, mutect2
- SVIL | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV63443857; called by mutect2, varscan2
- SZT2 | c.10031G>A p.R3344H (on ENST00000634258 / NM_001365999.1; = p.R3287H on NM_015284.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775799586, COSV65094651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1 | c.5401G>A p.G1801S (on ENST00000373790 / NM_138923.4; = p.G1822S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.296); catalogued as COSV52114762, COSV99334597; called by muse, mutect2, varscan2
- TANK | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52045282; called by muse, mutect2, varscan2
- TBX15 | c.767C>T p.S256L (on ENST00000369429 / NM_001330677.2; = p.S150L on NM_152380.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs1174595944, COSV99253605; called by muse, mutect2
- TEX14 | c.3548C>G p.S1183C (on ENST00000240361 / NM_001201457.2; = p.S1137C on NM_031272.5) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53617994; called by muse, mutect2, varscan2
- THADA | c.4268G>A p.G1423E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57684639; called by muse, mutect2, varscan2
- TNXB | c.11132C>G p.S3711C (on ENST00000647633; = p.S3464C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100925913; called by muse, mutect2
- TOGARAM1 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV63890763; called by muse, mutect2, varscan2
- TOP3B | c.576C>A p.F192L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100592337; called by muse, mutect2
- TRAF2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56038215; called by muse, mutect2, varscan2
- TRGV9 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.848); catalogued as rs1262147110; called by muse, mutect2, varscan2
- TSC2 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV54766150; called by muse, mutect2, varscan2
- TTN | c.39173C>G p.S13058C (on ENST00000591111; = p.S5634C on NM_003319.4) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | PolyPhen probably damaging (0.998); catalogued as rs1293270234, COSV100595515; ClinVar: uncertain significance; called by muse, mutect2
- UHRF1BP1 | c.3388A>T p.S1130C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV51956017; called by muse, mutect2, varscan2
- UNC13C | c.5461G>C p.D1821H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV52878588; called by muse, mutect2, varscan2
- XKR9 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV68773003; called by muse, mutect2, varscan2
- YARS2 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs776972394, COSV61401965, COSV61402239; called by muse, mutect2, varscan2
- ZNF335 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as COSV100532663; called by muse, mutect2
- ZNF534 | c.822G>C p.Q274H (on ENST00000332323 / NM_001143939.3; = p.Q261H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV56518138; called by muse, mutect2, varscan2
- ZNF780A | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs775299238, COSV100574971; called by muse, mutect2
- EAF1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- HLA-B | c.1066_1073del p.S356Vfs*41 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- KRT19 | c.1165_1166del p.D389Sfs*48 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- SOCS3 | c.299dup p.S101Qfs*42 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- TRAPPC10 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- AARS1 | c.1689G>T p.V563= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99933217; called by mutect2, varscan2
- AL592490.1 | c.504C>T p.I168= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV69426487; called by muse, mutect2, varscan2
- ATF6B | c.1947C>G p.V649= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100916798; called by muse, mutect2
- BRSK1 | c.1377G>A p.P459= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1321591963, COSV58667089; called by muse, mutect2
- CACNA1F | c.291C>G p.L97= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV59904770; called by muse, mutect2
- CASP2 | c.768G>A p.Q256= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1019753057, COSV100130866; called by muse, mutect2, varscan2
- CBWD1 | c.81G>C p.T27= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as COSV100070631; called by muse, mutect2, varscan2
- CDK11A | c.1461C>T p.T487= (on ENST00000378633 / NM_001313896.2; = p.T484= on NM_024011.4) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs777698249, COSV52307047, COSV99319302; called by muse, varscan2
- CPA1 | c.1242C>A p.T414= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1554412265, COSV99163219; called by muse, mutect2
- DISP1 | c.1914G>A p.G638= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs767929372, COSV52659768; called by muse, mutect2, varscan2
- DNAH10 | c.4878C>T p.F1626= (on ENST00000409039; = p.F1565= on NM_207437.3) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs773000743, COSV68987681; called by muse, mutect2
- DNAJC8 | c.726G>A p.L242= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99746055; called by muse, mutect2
- ERAL1 | c.78G>C p.A26= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV54739647; called by muse, mutect2, varscan2
- GBP5 | c.858C>G p.V286= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100599981; called by muse, mutect2
- GRHL3 | c.1071G>C p.L357= (on ENST00000350501 / NM_198174.3; = p.L362= on NM_021180.3) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV52567163; called by muse, mutect2, varscan2
- KCNF1 | c.1167C>T p.I389= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV54463846; called by muse, mutect2, varscan2
- KIF13B | c.3396G>A p.E1132= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV101580536; called by muse, mutect2
- KLK12 | c.534G>A p.G178= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99141801; called by muse, mutect2
- KRT10 | c.792G>A p.L264= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV54089911; called by muse, mutect2, varscan2
- LPAR4 | c.123C>G p.L41= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV70912724; called by muse, mutect2, varscan2
- LPXN | c.1071C>T p.F357= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1386505832, COSV67717265; called by muse, mutect2
- MRPL9 | c.258G>T p.T86= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV58618279; called by muse, mutect2, varscan2
- MYO3A | c.2220A>G p.Q740= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56333031; called by muse, mutect2, varscan2
- NECTIN4 | c.1254G>C p.L418= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV63512713, COSV63512832; called by mutect2, varscan2
- NGEF | c.1032C>T p.V344= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1417025146, COSV99888068; called by mutect2, varscan2
- OR6C6 | c.870C>G p.L290= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100626406; called by muse, mutect2
- PCDH15 | c.666T>C p.Y222= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV57320429; called by muse, mutect2, varscan2
- PDE1B | c.136T>C p.L46= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54493276; called by muse, mutect2, varscan2
- PDE6B | c.2001G>A p.T667= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1003542272, COSV55326986; called by muse, mutect2
- PDZD2 | c.3340C>T p.L1114= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV99223800; called by muse, mutect2
- PLEKHA3 | c.705C>G p.L235= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV52295586, COSV99317524; called by muse, mutect2
- RBP3 | c.2797C>T p.L933= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- RECQL | c.1581G>A p.L527= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs774747023, COSV53709556; called by mutect2, varscan2
- RIMBP3 | c.2637G>T p.G879= | Silent (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- RUFY2 | c.1366C>T p.L456= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99769132; called by muse, mutect2
- SEC16A | c.558G>A p.L186= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV51529233; called by muse, mutect2, varscan2
- SPECC1 | c.1803C>G p.L601= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99821313; called by muse, mutect2
- SPINDOC | c.201G>A p.P67= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs751270526, COSV53692705; called by muse, mutect2, varscan2
- TAS2R38 | c.750C>A p.V250= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV71885518; called by muse, mutect2
- TAS2R41 | c.48G>A p.L16= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV101281469; called by muse, mutect2
- TBXT | c.195C>G p.T65= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51618290; called by muse, mutect2, varscan2
- TONSL | c.3204G>A p.L1068= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV101340142; called by muse, mutect2, varscan2
- TPRX1 | c.1059C>T p.F353= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV59116003; called by muse, mutect2, varscan2
- TTN | c.97200G>A p.E32400= (on ENST00000591111; = p.E24976= on NM_003319.4) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV60099723; called by muse, mutect2, varscan2
- WIPF2 | c.690C>G p.V230= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV60272664, COSV60273818; called by muse, mutect2, varscan2
- XKR3 | c.696G>C p.P232= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs1273847434, COSV58885071, COSV58886398; called by muse, mutect2, varscan2
- ZNF324 | c.882C>T p.F294= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99543138; called by muse, mutect2
- ZNF34 | c.1486C>T p.L496= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs901454025, COSV58639749; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81147344 C>A | 5'Flank (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- EHMT2 | chr6:31901101 C>T | 5'Flank (SNP) | VAF 5/77 reads (6%) | catalogued as rs866429455, COSV100976948; called by muse, mutect2
- EXOC3 | chr5:442747 C>T | 5'Flank (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- UBTFL2 | n.915G>C | RNA (SNP) | VAF 4/36 reads (11%) | catalogued as rs1334719346; called by mutect2, varscan2
